TCGA case TCGA-24-2290 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2b14123b-8fcd-402c-9399-4e7c47f20252

Demographics
Sex at birth: female; Race: white; Age at index: 56 years; Vital status: Dead; Days to death: 1,102 days (3.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C48.1; Tissue or organ of origin: Specified parts of peritoneum; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: primary; Age at diagnosis: 56.2 years (20,530 days); Year of diagnosis: 1997; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 119 days; Number of cycles: 6; Treatment dose: 4,620 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 119 days; Number of cycles: 6; Treatment dose: 1,800 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 349 days; Days to treatment end: 412 days (1.1 years); Number of cycles: 4; Treatment dose: 3,000 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 349 days; Days to treatment end: 412 days (1.1 years); Number of cycles: 4; Treatment dose: 1,270 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 439 days (1.2 years); Days to treatment end: 550 days (1.5 years); Number of cycles: 6; Treatment dose: 707 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 578 days (1.6 years); Days to treatment end: 599 days (1.6 years); Number of cycles: 4; Treatment dose: 600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 607 days (1.7 years); Days to treatment end: 614 days (1.7 years); Number of cycles: 2; Treatment dose: 7,060 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 663 days (1.8 years); Days to treatment end: 705 days (1.9 years); Number of cycles: 3; Treatment dose: 279 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 663 days (1.8 years); Days to treatment end: 705 days (1.9 years); Number of cycles: 3; Treatment dose: 780 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 727 days (2.0 years); Days to treatment end: 823 days (2.3 years); Number of cycles: 5; Treatment dose: 60 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Plevitrexed; Initial disease status: Progressive Disease; Days to treatment start: 855 days (2.3 years); Days to treatment end: 939 days (2.6 years); Number of cycles: 5; Treatment dose: 2,250 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 1,005 days (2.8 years); Days to treatment end: 1,055 days (2.9 years).
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.1 years (20,854 days); Days to diagnosis: 324 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 324 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 324 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,102 days (3.0 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-24-2290-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 15.
  Slide TCGA-24-2290-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-24-2290-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Omentum; Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Vamydex; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,102 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,102 days; disease-free interval: event (new tumor event after initially disease-free), 324 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 324 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2290-01A-01D-0704-01): tumor purity 0.81, ploidy 3.66, whole-genome doublings 1.
